Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A74O, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A74O-01A (Primary Tumor).

Pathology Report for

Date of Surgery:

Diagnosis:

Right frontal lobe brain tumor
Anaplastic astrocytoma (grade III)
MIB-1 LI= 9.1%
IDH1- negative
P53: positive

ICD-O-3
Astrocytoma, grade III
9401/3
Site ~~Cere~~
Brain, supratentorial NOS C71.0
path
② Brain, frontal lobe C71.1

Discussion:

Sections demonstrate numerous scattered MIB-1 reactive cells. In the most proliferative areas, a labeling index of 9.1% is calculated. The neoplastic cells are diffusely positive for p53 but are negative for IDH1.

W 8/27/13

Microscopic Description:

Sections demonstrate a markedly hypercellular diffusely infiltrating glioma. The tumor cells resemble fibrillary S. wall the cystic astrocytes. Atypia is moderate. Scattered mitoses are seen with five mitoses identified first 10 high power fields examined. Microvascular proliferation is not seen. There is no confluent tumor necrosis although an area of infarct-like parenchymal necrosis is seen. Definite oligodendroglioma differentiation is identified.

W 8/27/13

Source: NCI Genomic Data Commons file f4c9b069-82b8-4b98-81f5-1302e58f4331 (TCGA-HT-A74O.0EA28E1A-D342-4149-95BB-EF81B43DA423.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).